Gene-level copy-number profile of tumor specimen TCGA-C5-A7CH-01A from TCGA case TCGA-C5-A7CH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.2 years (15,777 days).
Specimen TCGA-C5-A7CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5ecac012-db86-4783-9279-770e325d40b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A7CH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec0051f3-9ef4-49a3-a5eb-42da87f0af4f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,506; copy number 3: 19,493; copy number 4: 19,449; copy number 5: 11,108; copy number 6: 3,065; copy number 7: 3,588; copy number 8: 1,476; copy number 11: 34; copy number 14: 24; copy number 45: 32; copy number 46: 17; copy number 50: 14; copy number 60: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A7CH-01A-11D-A33N-01): tumor purity 0.67, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,012 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,623,284, 32 genes, copy number 45: PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41.
- chr3:145,824,257–198,222,513, 931 genes, copy number 7–8 (broad region; genes not listed).
- chr9:13,105,706–16,061,663, 42 genes, copy number 46–60 (within-gene range 3–60): MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P.
- chr11:101,451,564–101,872,562, 1 gene, copy number 11 (within-gene range 6–11): TRPC6.
- chr11:101,584,295–103,895,271, 51 genes, copy number 11–14 (within-gene range 3–14): AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1.
- chr11:111,040,098–111,179,641, 6 genes, copy number 11: RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1.
- chr12:68,332,888–72,728,844, 87 genes, copy number 7 (broad region; genes not listed).
- chr13:63,034,668–114,337,626, 606 genes, copy number 7 (broad region; genes not listed).
- chr14:23,185,316–37,187,314, 289 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:37,595,847–92,839,947, 967 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
